Somatic mutation profile of tumor specimen TCGA-EM-A22K-01A (aliquot TCGA-EM-A22K-01A-11D-A17V-08) from TCGA case TCGA-EM-A22K, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVA; Age at diagnosis: 46.2 years (16,890 days).
Specimen TCGA-EM-A22K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c4b3698-8d57-4168-9f31-5d1248fac8eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A22K-10A (Blood Derived Normal), aliquot TCGA-EM-A22K-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b69f3f0-6bd6-43bd-a580-f9dc05559761

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 53/142 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs28933406, COSV54236740, COSV54240324, COSV54242140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP11 | c.1822A>T p.K608* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV50293251; called by muse, mutect2, varscan2
- ANTXR2 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV55017490; called by muse, mutect2, varscan2
- DLGAP5 | c.1366G>C p.E456Q | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.251); catalogued as COSV55962297; called by muse, mutect2, varscan2
- LAMP5 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.037); catalogued as rs527594563, COSV55715265; called by muse, mutect2, varscan2
- XPNPEP1 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs372041068; called by muse, mutect2, varscan2
- NFAT5 | c.4482A>G p.Q1494= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV63025524; called by muse, mutect2, varscan2
